Gene-level copy-number profile of tumor specimen TCGA-XF-A9SK-01A from TCGA case TCGA-XF-A9SK, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 65.8 years (24,019 days).
Specimen TCGA-XF-A9SK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.6434448d-2105-4810-8a1f-66832a3b5f17.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-A9SK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d4bf4f21-c680-446f-91db-7c0138d4881b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 76; copy number 1: 11; copy number 2: 20,428; copy number 3: 18,778; copy number 4: 13,131; copy number 5: 3,020; copy number 6: 1,560; copy number 7: 865; copy number 8: 1,216; copy number 9: 306; copy number 10: 190; copy number 11: 91; copy number 12: 2; copy number 13: 79; copy number 16: 11; copy number 20: 22; copy number 26: 1; copy number 50: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-A9SK-01A-11D-A42D-01): tumor purity 0.47, ploidy 3.14, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 75 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:10,532,145–10,632,203, 3 genes: AL135790.2, PTPRD-AS2, AL135790.1.
- chr9:21,058,771–24,592,104, 72 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,801 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:59,733,227–62,178,675, 25 genes, copy number 7–9 (within-gene range 2–9): MIR4711, AL035416.1, HOOK1, CYP2J2, RN7SL475P, C1orf87, PGBD4P8, LINC02778, LINC01748, AC099792.1, NFIA, NFIA-AS2, NFIA-AS1, AC099791.3, AC099791.4, AC099791.1, TM2D1, AC099791.2, PATJ, RNU6-414P, RNU6-1177P, LAMTOR5P1, RN7SL180P, MIR3116-1, MIR3116-2.
- chr2:180,967,248–181,076,585, 1 gene, copy number 7 (within-gene range 5–7): UBE2E3.
- chr2:181,076,051–181,680,665, 6 genes, copy number 7 (within-gene range 5–7): AC068196.1, LINC01934, MIR4437, AC020595.1, ITGA4, CERKL.
- chr2:186,354,570–187,565,760, 15 genes, copy number 8 (within-gene range 2–8): AC017071.1, MED28P3, ZC3H15, DPRXP1, ITGAV, AC017101.1, FAM171B, ZSWIM2, IMPDH1P7, AC007319.1, RN7SKP42, RNU6-989P, CALCRL, GAPDHP59, TFPI.
- chr3:97,759,523–97,821,884, 3 genes, copy number 8: AC110491.1, ARL6, AC110491.3.
- chr3:152,648,146–155,745,071, 44 genes, copy number 7–9 (within-gene range 4–9): AC092924.1, AC092924.2, ATP5MGP5, P2RY1, HMGN2P13, AC117394.1, AC117394.2, RAP2B, RN7SL300P, AC078788.1, AC078788.2, LINC02006, LINC02877, RNU6-901P, Y_RNA, AC068985.1, U8, RPL21P42, ARHGEF26-AS1, ARHGEF26, DHX36, AC134026.1, AC134026.2, GPR149, DDX50P2, AC092994.1, SYPL1P1, DYNLL1P5, RPL9P15, AC073359.2, AC073359.1, MME, MME-AS1, LINC01487, STRIT1, AC104831.1, PABPC1P10, PLCH1, AC108729.3, AC108729.2, AC108729.1, RN7SL715P, PLCH1-AS1, PLCH1-AS2.
- chr5:7,980,146–45,895,970, 553 genes, copy number 7 (broad region; genes not listed).
- chr7:54,185,071–54,257,577, 1 gene, copy number 9 (within-gene range 4–9): AC092848.2.
- chr7:54,330,670–62,275,678, 156 genes, copy number 7–13 (broad region; genes not listed).
- chr8:37,095,150–37,899,497, 21 genes, copy number 12–50 (within-gene range 4–50): SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1.
- chr8:38,974,228–41,578,421, 42 genes, copy number 7–20 (within-gene range 2–20): HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, AC022733.1, SIRLNT, AC105999.1, AC010857.1, ZMAT4, AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4.
- chr8:137,105,352–137,698,467, 4 genes, copy number 7 (within-gene range 4–7): RNU6-144P, ZYXP1, AC105213.1, AC110053.1.
- chr10:44,712–9,309,772, 172 genes, copy number 8–9 (broad region; genes not listed).
- chr10:21,481,716–30,115,494, 155 genes, copy number 7–8 (broad region; genes not listed).
- chr10:37,348,616–38,617,344, 35 genes, copy number 7: VN1R53P, TACC1P1, MTND1P18, MTRNR2L7, AL132657.1, ZNF248, AL132657.2, ZNF33BP1, TLK2P2, AL135791.1, ZNF37CP, ZNF33CP, ZNF25, ZNF25-DT, Y_RNA, ZNF33A, RNU6-795P, AL161931.1, EIF3LP3, FXYD6P2, ZNF37A, AL117339.4, AL117339.3, AL117339.1, CCNYL4, AL133217.1, AL117339.2, HSD17B7P2, SEPTIN7P9, AL133216.2, RNU6-1118P, CICP9, AL133216.1, ABCD1P2, AL133173.2.
- chr12:126,191,151–133,214,832, 212 genes, copy number 7–10 (within-gene range 5–10) (broad region; genes not listed).
- chr16:69,187,129–69,309,052, 1 gene, copy number 8 (within-gene range 6–8): SNTB2.
- chr16:69,299,682–70,686,053, 57 genes, copy number 8: AC026464.4, VPS4A, COG8, PDF, AC026464.6, AC026464.3, AC026464.1, NIP7, TMED6, TERF2, CYB5B, AC026464.5, AC026464.2, NFAT5, MIR1538, AC009032.1, AC012321.1, NQO1, AC092115.2, AC092115.3, NOB1, AC092115.1, WWP2, SNORA62, MIR140, CLEC18A, AC026468.1, PDXDC2P-NPIPB14P, NPIPB14P, PDXDC2P, MIR1972-2, AC009022.1, PDPR, AC009060.1, CLEC18C, AC009060.2, SMG1P7, EXOSC6, AARS1, RN7SL279P, DDX19B, AC012184.2, AC012184.3, DDX19A, AC012184.4, ST3GAL2, AC012184.1, RPS27P26, RNU6-23P, FCSK, COG4, SF3B3, SNORD111B, SNORD111, IL34, MTSS2, AC020763.4.
- chr16:70,713,987–70,716,890, 1 gene, copy number 8: AC020763.3.
- chr16:72,112,157–77,660,570, 118 genes, copy number 8–11 (within-gene range 4–11) (broad region; genes not listed).
- chr16:78,099,430–79,212,667, 1 gene, copy number 10 (within-gene range 6–11): WWOX.
- chr16:78,166,717–81,033,114, 47 genes, copy number 8–11 (within-gene range 6–11): AC009044.1, WWOX-AS1, AC106743.1, LSM3P5, AC046158.1, AC046158.4, AC046158.2, AC046158.3, AC009141.1, RPS3P7, AC136603.1, AC027279.4, AC027279.1, AC027279.3, AC027279.2, AC009145.4, AC009145.3, AC009145.1, AC009145.2, AC092376.2, AC092376.3, AC092376.1, RNA5SP431, AC084064.1, MAF, AC009159.2, AC009159.3, AC009159.1, AC009159.4, LINC01229, MAFTRR, LINC01228, AC092130.1, AC022166.1, AC105411.1, AC022166.2, DYNLRB2, AC108097.1, LINC01227, CDYL2, AC092332.1, AC099313.1, ARLNC1, AC009070.1, CMC2, AC092718.7, CENPN.
- chr16:82,688,931–82,990,298, 6 genes, copy number 8: MIR8058, AC099506.2, AC099506.1, AC099506.3, RN7SL134P, AC125793.1.
- chr16:88,715,338–88,785,220, 1 gene, copy number 8 (within-gene range 6–8): PIEZO1.
- chr16:88,731,180–89,740,925, 46 genes, copy number 8 (within-gene range 4–8): AC138028.2, AC138028.5, AC138028.1, CDT1, APRT, GALNS, TRAPPC2L, PABPN1L, CBFA2T3, AC092384.2, AC092384.3, AC092384.1, AC135782.2, AC135782.1, ACSF3, AC135782.3, LINC00304, LINC02138, CDH15, SLC22A31, AC009113.1, ZNF778, AC009113.2, ANKRD11, AC137932.3, AC137932.1, AC137932.2, AC092120.1, AC092120.3, RNU6-430P, AC092120.2, SPG7, AC092123.1, RPL13, SNORD68, CPNE7, DPEP1, CHMP1A, SPATA33, AC010538.1, CDK10, LINC02166, SPATA2L, VPS9D1, VPS9D1-AS1, ZNF276.
- chr19:49,119,544–58,605,223, 731 genes, copy number 8 (broad region; genes not listed).
- chr20:31,257,664–32,101,856, 45 genes, copy number 13: DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK.
- chr20:35,699,272–35,959,472, 11 genes, copy number 16: ROMO1, RBM39, RPF2P1, U6, PHF20, COX7BP2, Y_RNA, HIGD1AP16, RNU4-40P, RNU6-937P, SCAND1.
- chr20:36,751,791–36,951,843, 5 genes, copy number 7: DSN1, SOGA1, RN7SL156P, TLDC2, SAMHD1.
- chr20:44,656,451–56,786,087, 286 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
